Surgical pathology report (de-identified scan), TCGA case TCGA-31-1953, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Imperial College, specimen TCGA-31-1953-01A (Primary Tumor).

[page 1 of 2]
Consent: Consent unknown (not checked)

Specimen Type:

A: Uterus, TUBES, OVARIES, MASS

B: Omentum

Clinical Details:

Ovarian cancer

CGA-31-1953

Macroscopic Description:

A) UTERUS, TUBES, OVARIES and MASS: The uterus measures 8 cm in length and 6 cm transversally. There is an intramural fibroid in the fundic region, measuring 2 cm in diameter. The endometrium is 0.3 cm thick and the maximum myometrial thickness is 1.8 cm. There is focal thickening of the serosa of the uterus.

There are separate ovarian masses that measure 8.5 x 6 x 4.5 cm and 9 x 7 x 4 cm. Both ovarian masses show friable papillary tumour on the surface. The cut surface of the masses reveals necrotic friable white tumour tissue. One of the ovarian masses has a stretched and distorted fallopian tube on the surface, which measures 5 cm in length and 0.6 cm in diameter. A fallopian tube is not macroscopically identified in the second ovarian mass.

Block: A 1 – A8, 1pc each ovarian mass with capsule, A6 & A7 with sections with tube

A 9 – A16, 1pc each other mass, A12 & A13 represent tube

A17 – multi pieces right parametria

A18 – multi pieces left parametria

A19 – 1pc anterior cervix

A20 – 1pc posterior cervix

A21 – 1pc lower uterine segment

A22 – A23 1pc each together one complete TS of endometrium and myometrium with thickened peritoneal reflection

A24 – 1pc fibroid

[page 2 of 2]
A25 – 1pc posterior wall of uterus with endometrium and myometrium. [REDACTED]

B) OMENTUM: This is omental tissue measuring 28 x 20 x 2 cm, containing tumour deposits. The largest of the deposits measures 2.5 x 2.5 x 2 cm.

Block: B 1 – B 4, 1pc each [REDACTED]

[REDACTED] TCGA-31-1953 [REDACTED]

Microscopic Description:

A) UTERUS, TUBES and OVARIES: Sections from both ovarian masses show similar morphological features. The ovarian parenchyma is extensively infiltrated by serous papillary carcinoma, Grade III. The tumour shows papillary architecture and solid sheets. The tumour cells have markedly atypical nuclei, featuring prominent nucleoli and coarse chromatin. There is brisk mitotic activity and focal necrosis. The entrapped fallopian tubes in both the ovarian masses are free from tumour infiltration.

The endometrium is inactive. The myometrium contains foci of adenomyosis. There are metastatic tumour deposits of serous carcinoma on the serosal surface and focally infiltrating the uterine wall. The cervix and parametrial tissue are free of tumour.

B) OMENTUM: The omentum shows multiple metastatic deposits of serous carcinoma.

The tumour cells express ER (Allred's score 7), PgR (Allred's score 3) and WT-1. Few cells weakly express p53.

Final Diagnosis:

A) UTERUS, TUBES and OVARIES: **BILATERAL OVARIAN SEROUS PAPILLARY CARCINOMA, GRADE III, STAGE IIIC**

B) OMENTUM: **METASTATIC SEROUS PAPILLARY CARCINOMA**

Additional Pathologist(s)/BMS(s)

[REDACTED]

Source: NCI Genomic Data Commons file d2713d81-8a63-4c88-b485-f5560dfb6d2d (TCGA-31-1953.C824400D-B062-4A04-B805-F717426D688E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).